Somatic mutation profile of tumor specimen C3L-08973-04 (aliquot CPT0497980006) from CPTAC case C3L-08973, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 61.9 years (22,605 days).
Specimen C3L-08973-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b751ed75-a69d-46a2-8b06-c029e0af591b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08973-31 (Blood Derived Normal), aliquot CPT0498100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1446096f-93f8-425f-bcc2-575fff7dfae5

The open-access MAF lists 1,887 somatic variants for this specimen: 1,388 protein-altering or splice-affecting, 416 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,011, Silent 416, Frame Shift Del 258, Intron 45, Frame Shift Ins 39, Nonsense Mutation 36, Splice Region 18, 3'UTR 14, In Frame Del 12, 5'Flank 10, Splice Site 8, 5'UTR 6.

Variants (750 of 1,887; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.2176del p.Y726Tfs*53 | Frame Shift Del (DEL) | VAF 63/415 reads (15%) | catalogued as rs771459937; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ARID1A | c.5966G>A p.R1989Q | Missense Mutation (SNP) | VAF 61/423 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773909963, COSV61375267, COSV61389574; called by muse, mutect2, varscan2
- CDKN1C | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 69/384 reads (18%) | catalogued as rs797045445, CM103077, COSV57832368; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 44/276 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 64/401 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs140656187, COSV57258562; called by muse, mutect2, varscan2
- ERBB3 | c.1063A>C p.T355P | Missense Mutation (SNP) | VAF 27/221 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57251216, COSV57256291; called by muse, mutect2, varscan2
- ERBB3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs931676601, COSV57250012; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNPTAB | c.2693del p.K898Sfs*13 | Frame Shift Del (DEL) | VAF 54/254 reads (21%) | catalogued as rs281864999, CD090839; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 53/406 reads (13%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MFRP | chr11:119345562 ins G | 5'Flank (INS) | VAF 65/336 reads (19%) | catalogued as rs587776596; ClinVar: pathogenic; called by mutect2, varscan2
- MYBPC3 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 65/410 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753321277, COSV57024982; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PHYH | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 78/432 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770262329, CM001293; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRKDC | c.8819G>A p.R2940H | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs372587440; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAB11B | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs1555690779; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RXYLT1 | c.139del p.A47Rfs*42 | Frame Shift Del (DEL) | VAF 57/455 reads (13%) | catalogued as rs397514696; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC5A7 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs147656110, COSV50902580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMPX | c.99del p.R34Efs*47 | Frame Shift Del (DEL) | VAF 61/387 reads (16%) | catalogued as rs398122930, CD130105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 101/620 reads (16%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA2 | c.2786T>C p.M929T (on ENST00000614293; = p.M899T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/541 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1430073421; called by muse, mutect2, varscan2
- ABCB1 | c.2000C>A p.S667* | Nonsense Mutation (SNP) | VAF 44/334 reads (13%) | catalogued as COSV99712221; called by muse, mutect2, varscan2
- ABCD1 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 92/691 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs782499252; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 33/208 reads (16%) | catalogued as rs749606695; called by mutect2, varscan2
- ACAN | c.6201del p.F2067Lfs*25 | Frame Shift Del (DEL) | VAF 50/391 reads (13%) | catalogued as rs1567187950; called by mutect2, pindel, varscan2
- ACTB | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs11546912, COSV59320776; called by muse, varscan2
- ACTL7B | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 118/720 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV104424614; called by muse, mutect2
- ADAM12 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs752809671; called by muse, mutect2, varscan2
- ADAMTS19 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as rs1429187560; called by muse, mutect2, varscan2
- ADAMTS9 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs771577187; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4784G>A p.R1595Q | Missense Mutation (SNP) | VAF 83/581 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs558895939; called by muse, mutect2, varscan2
- ADD2 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 59/457 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs782225461, COSV52463971; called by muse, mutect2, varscan2
- ADGRB1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 111/752 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1394784678; called by muse, mutect2, varscan2
- ADGRB1 | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs779819826; called by muse, mutect2, varscan2
- ADGRL3 | c.2368G>T p.G790* (on ENST00000506720 / NM_001322402.2; = p.G722* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 38/306 reads (12%) | catalogued as COSV101547384, COSV72229766; called by muse, mutect2, varscan2
- ADPRHL1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs376266488, COSV100733568; called by muse, mutect2, varscan2
- AGAP2 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 93/631 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as rs1376832059; called by muse, mutect2, varscan2
- AGO1 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs935068063, COSV64595317; called by muse, mutect2, varscan2
- AGO2 | c.2201C>T p.T734M | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766748578, COSV99596072; called by muse, mutect2, varscan2
- AHRR | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370185168, COSV100326395; called by muse, mutect2, varscan2
- AKAP9 | c.11751A>G p.I3917M (on ENST00000359028; = p.I3893M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV50151832; called by muse, mutect2, varscan2
- AKR1B15 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373958065; called by muse, varscan2
- AKT1 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as rs781339141; ClinVar: uncertain significance; called by muse, mutect2
- ALB | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs267600248, COSV55736977, COSV55739910; called by muse, mutect2, varscan2
- ALDH18A1 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 53/429 reads (12%) | catalogued as rs1325257479; called by muse, mutect2, varscan2
- ALDH9A1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs752528835, COSV100699283; called by muse, mutect2, varscan2
- ALKBH7 | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 66/448 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1222635055; called by muse, varscan2
- ALOX12B | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 62/460 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs779456276; called by mutect2, varscan2
- ALPK3 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 47/389 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1483975709, COSV99034307; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 37/284 reads (13%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKK1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 97/517 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); catalogued as rs751344795; called by muse, mutect2, varscan2
- ANKRD16 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs746509178; called by muse, mutect2
- ANKS6 | c.433del p.A145Pfs*16 | Frame Shift Del (DEL) | VAF 78/601 reads (13%) | catalogued as rs1564229265, COSV62051272; called by mutect2, pindel, varscan2
- APAF1 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 66/378 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745962333; called by muse, mutect2, varscan2
- APC | c.8275C>T p.R2759C | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755366812; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEX2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 75/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755988566; called by muse, mutect2, varscan2
- AREG | c.334del p.Q112Kfs*51 | Frame Shift Del (DEL) | VAF 51/316 reads (16%) | catalogued as rs757742243; called by mutect2, pindel, varscan2
- ARHGAP10 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331228; called by muse, mutect2, varscan2
- ARHGEF2 | c.2629C>T p.R877C (on ENST00000361247 / NM_001162383.2; = p.R849C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/542 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs771478589; called by muse, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 80/565 reads (14%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1B | c.2754G>T p.M918I | Missense Mutation (SNP) | VAF 66/437 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1396513955; called by muse, mutect2, varscan2
- ARMC1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs773610877; called by muse, mutect2, varscan2
- ARR3 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 66/468 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs145241324; called by muse, mutect2, varscan2
- ASB13 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 73/516 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs777518625; called by muse, mutect2, varscan2
- ASB14 | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs769875167; called by muse, mutect2, varscan2
- ASH1L | c.3839G>A p.R1280Q | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.92); catalogued as rs776802029; called by muse, mutect2, varscan2
- ASTN2 | c.3989G>A p.R1330Q (on ENST00000313400 / NM_001365069.1; = p.R1279Q on NM_014010.5) | Missense Mutation (SNP) | VAF 47/381 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.978); catalogued as rs367824366; called by muse, mutect2, varscan2
- ATP2B1 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1352868810, COSV53810568; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 58/339 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs761913726, COSV57749833; called by muse, mutect2, varscan2
- AUTS2 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs775004644; called by muse, mutect2, varscan2
- B3GALT5 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV58200611; called by muse, varscan2
- B3GNT3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 82/461 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752385665, COSV59438987; called by muse, mutect2, varscan2
- B4GALNT2 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.426); catalogued as COSV55924579; called by muse, mutect2, varscan2
- B9D2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 116/572 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs149500212; called by muse, mutect2, varscan2
- BASP1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 116/672 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as rs758198878; called by muse, mutect2, varscan2
- BBX | c.581A>G p.Q194R | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1273805645; called by muse, mutect2, varscan2
- BCOR | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 73/519 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs1452619451, COSV60721497; called by muse, mutect2, varscan2
- BCOR | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 60/481 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV60709001; called by muse, mutect2, varscan2
- BECN2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 76/455 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs546258943; called by muse, mutect2, varscan2
- BICC1 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 14/361 reads (4%) | catalogued as COSV54063839; called by muse, mutect2
- BOD1L1 | c.8392G>A p.A2798T | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs774507896, COSV50009015; called by muse, mutect2, varscan2
- BSN | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 97/548 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs377329284; called by muse, mutect2, varscan2
- BTF3L4 | c.135dup p.L46Tfs*5 | Frame Shift Ins (INS) | VAF 29/197 reads (15%) | catalogued as rs1558005082; called by mutect2, varscan2
- BX276092.9 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 91/460 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as rs745987041; called by muse, mutect2, varscan2
- C11orf71 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 95/522 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.023); catalogued as rs1166463688; called by muse, mutect2, varscan2
- C5orf51 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as rs752413502, COSV67566490; called by muse, mutect2, varscan2
- C7orf33 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs780799842, COSV100188929; called by muse, mutect2, varscan2
- CA7 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.255); catalogued as rs775071324; called by muse, mutect2, varscan2
- CACNA1H | c.6727dup p.D2243Gfs*17 | Frame Shift Ins (INS) | VAF 74/515 reads (14%) | catalogued as rs753624103; called by mutect2, varscan2
- CACNA1S | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 69/493 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs779799849, COSV100755369; called by muse, mutect2, varscan2
- CAD | c.5512C>T p.R1838C | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs918556853; called by muse, varscan2
- CAMTA2 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 32/260 reads (12%) | catalogued as rs147496832; called by muse, varscan2
- CAP2 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 59/390 reads (15%) | catalogued as rs1051374930; called by muse, mutect2, varscan2
- CARD9 | c.1303T>C p.S435P | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59996265; called by muse, mutect2, varscan2
- CCDC168 | c.8528del p.N2843Mfs*7 | Frame Shift Del (DEL) | VAF 64/415 reads (15%) | catalogued as rs1432338958; called by mutect2, pindel, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 22/225 reads (10%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC8 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 94/518 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.36); catalogued as rs762887541; called by muse, mutect2, varscan2
- CCDC92 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769500480, COSV99435306; called by muse, varscan2
- CCR7 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 54/441 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs947333410, COSV55849053; called by muse, mutect2, varscan2
- CD151 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 62/313 reads (20%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.806); catalogued as rs758951148, COSV100431784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD93 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 67/535 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1489790839, COSV55663553; called by muse, mutect2, varscan2
- CDC7 | c.126del p.D43Ifs*39 | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | catalogued as COSV99319917; called by mutect2, pindel, varscan2
- CDH18 | c.1766G>T p.C589F | Missense Mutation (SNP) | VAF 77/478 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56908106; called by muse, mutect2, varscan2
- CDH20 | c.2170A>G p.S724G | Missense Mutation (SNP) | VAF 80/567 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs757119618; called by muse, mutect2, varscan2
- CDH5 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs368052920; called by muse, mutect2, varscan2
- CDT1 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 57/450 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs558748090; called by muse, mutect2
- CENPP | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 20/485 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55334898; called by muse, mutect2
- CEP164 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs139763142; called by muse, mutect2, varscan2
- CEP164 | c.3623G>A p.G1208D | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99634512; called by muse, mutect2, varscan2
- CEP290 | c.7341del p.K2447Nfs*10 | Frame Shift Del (DEL) | VAF 41/297 reads (14%) | catalogued as rs281865189; ClinVar: not provided; called by mutect2, pindel, varscan2
- CES1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 29/418 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1351062972, COSV62086174; called by muse, mutect2
- CFAP61 | c.766T>C p.C256R | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV55645906; called by muse, varscan2
- CFHR2 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs778719259; called by muse, mutect2, varscan2
- CFHR5 | c.533dup p.N178Kfs*20 | Frame Shift Ins (INS) | VAF 42/337 reads (12%) | catalogued as rs746586384; called by mutect2, pindel, varscan2
- CHD2 | c.33_35del p.E11del | In Frame Del (DEL) | VAF 46/420 reads (11%) | catalogued as rs772244385; called by pindel, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 34/213 reads (16%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHL1 | c.658A>G p.M220V | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs756748567; called by muse, mutect2
- CHST6 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 113/664 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.333); catalogued as COSV59999636; called by muse, mutect2, varscan2
- CIAO3 | c.953del p.G318Afs*27 | Frame Shift Del (DEL) | VAF 86/580 reads (15%) | catalogued as rs1442970889; called by mutect2, pindel, varscan2
- CLCC1 | c.1595G>A p.S532N (on ENST00000356970 / NM_001377464.1; = p.S482N on NM_015127.5) | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV99915159; called by muse, mutect2, varscan2
- CLSTN2 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs370226511; called by muse, mutect2, varscan2
- CMTR1 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs755231746, COSV65089383; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 35/234 reads (15%) | catalogued as rs758676375; called by mutect2, varscan2
- COL3A1 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1393337508; called by muse, mutect2, varscan2
- CPNE8 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 42/364 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58850329; called by muse, mutect2, varscan2
- CRACD | c.501del p.K167Nfs*82 | Frame Shift Del (DEL) | VAF 61/382 reads (16%) | catalogued as rs1180697484, COSV99950174; called by mutect2, pindel, varscan2
- CRYBA2 | c.162T>C p.V54= | Splice Region (SNP) | VAF 18/308 reads (6%) | catalogued as COSV99838086; called by muse, mutect2
- CSMD1 | c.5791C>T p.R1931W (on ENST00000520002; = p.R1930W on NM_033225.6) | Missense Mutation (SNP) | VAF 45/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257992819, COSV59378890; called by muse, mutect2, varscan2
- CSMD2 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772203139, COSV53930786; called by muse, mutect2, varscan2
- CSMD3 | c.7955C>T p.T2652M (on ENST00000297405 / NM_001363185.1; = p.T2548M on NM_052900.3) | Missense Mutation (SNP) | VAF 50/407 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757060591, COSV52186438, COSV52276704, COSV99835151; called by muse, mutect2, varscan2
- CSMD3 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs1391324453; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 36/264 reads (14%) | catalogued as rs767756120; called by mutect2, varscan2
- CTNNB1 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 58/448 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.155); catalogued as COSV62697081; called by muse, mutect2, varscan2
- CTR9 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV63728224; called by muse, mutect2
- CUBN | c.5149G>A p.V1717I | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs769662282, COSV64712705; called by muse, mutect2, varscan2
- CUX1 | c.1289dup p.P431Sfs*16 | Frame Shift Ins (INS) | VAF 54/422 reads (13%) | catalogued as rs782381199; called by mutect2, varscan2
- CUX2 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 88/597 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1268769789, COSV99919319; called by muse, mutect2, varscan2
- CYGB | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 59/414 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.24); catalogued as rs200693197; called by muse, mutect2, varscan2
- CYHR1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 93/690 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as rs1238168263; called by muse, mutect2, varscan2
- CYP2B6 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs565530668; called by muse, mutect2
- CYP3A43 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs771535128, COSV55935203; called by muse, mutect2, varscan2
- DAGLA | c.2650G>A p.G884S | Missense Mutation (SNP) | VAF 110/619 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs778135090, COSV57198343; called by muse, mutect2
- DAPK2 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1244714096; called by muse, mutect2, varscan2
- DCAF12L1 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 36/648 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1451093436, COSV64421106; called by muse, mutect2
- DCAF12L2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 85/573 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776609885, COSV100758723, COSV63580588; called by muse, mutect2, varscan2
- DCHS1 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 72/453 reads (16%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.988); catalogued as rs144417386, COSV55034118; called by muse, mutect2, varscan2
- DCLK1 | c.1569A>C p.Q523H | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99712388; called by muse, mutect2, varscan2
- DCLK3 | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339233202, COSV69363925; called by muse, mutect2, varscan2
- DEF6 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1486017452; called by muse, mutect2, varscan2
- DEPDC1 | c.2105del p.K702Rfs*45 (on ENST00000456315 / NM_001114120.3; = p.K418Rfs*45 on NM_017779.6) | Frame Shift Del (DEL) | VAF 19/204 reads (9%) | catalogued as COSV63959626; called by mutect2, pindel
- DGKA | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1306876397; called by muse, mutect2, varscan2
- DGKI | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761224295, COSV55969021, COSV55969848; called by muse, mutect2, varscan2
- DIP2A | c.4207G>A p.V1403I | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370497841; called by muse, mutect2, varscan2
- DISP3 | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 82/431 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs774915287; called by muse, mutect2, varscan2
- DLC1 | c.1742C>T p.T581M (on ENST00000276297 / NM_001348081.2; = p.T144M on NM_006094.5) | Missense Mutation (SNP) | VAF 88/746 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757570932, COSV52292418; called by muse, mutect2, varscan2
- DLGAP2 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs894944884; called by muse, mutect2, varscan2
- DMRTB1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 106/643 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV65113739; called by muse, mutect2, varscan2
- DNAAF3 | c.701G>A p.R234Q (on ENST00000524407 / NM_001256715.2; = p.R281Q on NM_178837.4) | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs770641126, COSV100787921; called by muse, mutect2, varscan2
- DNAH1 | c.6973C>T p.R2325C | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201265486; called by muse, mutect2, varscan2
- DNAH17 | c.8044C>T p.R2682C | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749280148, COSV101103505; called by muse, mutect2, varscan2
- DNAH2 | c.10444C>T p.R3482C | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs374920784; called by muse, mutect2, varscan2
- DNAH3 | c.4629C>A p.D1543E | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54519726; called by muse, mutect2, varscan2
- DNAH5 | c.8092G>A p.V2698M | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs773466223; called by muse, mutect2, varscan2
- DNAH8 | c.8003A>G p.Q2668R | Missense Mutation (SNP) | VAF 50/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762400523; called by muse, mutect2, varscan2
- DNAJC1 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV65409788; called by muse, mutect2, varscan2
- DNAJC4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 54/439 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs755040167; called by muse, mutect2, varscan2
- DNER | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 90/585 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as rs1208353976; called by muse, varscan2
- DOCK1 | c.4888C>G p.R1630G | Missense Mutation (SNP) | VAF 47/455 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV54738728, COSV99732387; called by muse, mutect2, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 32/240 reads (13%) | catalogued as rs1559599687; called by mutect2, varscan2
- DOCK4 | c.5735G>A p.R1912H | Missense Mutation (SNP) | VAF 72/560 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs759774429; called by muse, varscan2
- DOCK9 | c.3062C>T p.A1021V (on ENST00000376460 / NM_001366676.2; = p.A1022V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.168); catalogued as rs756028718, COSV59636238; called by muse, mutect2, varscan2
- DPP3 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs199640937, COSV64757924, COSV64758556; called by muse, mutect2, varscan2
- DPP7 | c.1322del p.G441Efs*33 | Frame Shift Del (DEL) | VAF 68/469 reads (14%) | catalogued as rs759556695; called by pindel, varscan2
- DPP7 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 83/603 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs752133249; called by muse, mutect2, varscan2
- DRD5 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 44/415 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs762703888; called by muse, mutect2
- DYDC2 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 58/483 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV99058834, COSV99758010; called by muse, mutect2, varscan2
- DYNC2I1 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68104144; called by muse, mutect2, varscan2
- EHMT1 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs774046148; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- EIF2AK4 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.797); catalogued as rs750136639, COSV55464890; called by muse, mutect2, varscan2
- EIF3A | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 70/514 reads (14%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.97); catalogued as rs1418339157; called by muse, mutect2, varscan2
- EMID1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 78/508 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs555505087, COSV61830096; called by muse, mutect2, varscan2
- EML6 | c.5633G>A p.R1878Q | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1322561581, COSV58271722; called by muse, mutect2, varscan2
- EMSY | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1015568567, COSV58265540; called by muse, mutect2, varscan2
- ENO4 | c.1759del p.Y587Tfs*31 (on ENST00000622726; = p.Y584Tfs*31 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 46/280 reads (16%) | catalogued as rs763733545, COSV53387848; called by mutect2, varscan2
- ENTPD4 | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775070986, COSV62268453; called by muse, mutect2
- EPAS1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs776459473, COSV55384997; called by muse, mutect2, varscan2
- EPC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433910452, COSV53923041; called by muse, mutect2, varscan2
- EPDR1 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs750207754, COSV99554150; called by muse, mutect2, varscan2
- EPPK1 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 81/776 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.466); catalogued as rs1554661655; called by muse, mutect2
- ERC1 | c.3086A>G p.H1029R (on ENST00000360905 / NM_178040.4; = p.H1001R on NM_178039.4) | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); catalogued as rs1390697380; called by muse, mutect2, varscan2
- ERICH3 | c.4046C>T p.T1349M | Missense Mutation (SNP) | VAF 85/488 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58612352; called by muse, mutect2, varscan2
- ESR1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 44/373 reads (12%) | catalogued as CM016135; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 68/434 reads (16%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT1 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1399393194; called by muse, mutect2, varscan2
- EWSR1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs772636858, COSV100132071, COSV58421516; called by muse, mutect2, varscan2
- EXOC6 | c.850del p.S284Pfs*56 | Frame Shift Del (DEL) | VAF 30/269 reads (11%) | catalogued as COSV53318711; called by mutect2, pindel, varscan2
- EXPH5 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs745852967; called by muse, mutect2, varscan2
- EYS | c.702T>A p.N234K | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60992639; called by muse, mutect2, varscan2
- EYS | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.996); catalogued as rs144074328; ClinVar: uncertain significance; called by muse, mutect2
- F12 | c.935A>G p.H312R | Missense Mutation (SNP) | VAF 89/614 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1204188470, COSV53691141; called by muse, mutect2, varscan2
- FABP6 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 57/425 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1189275630; called by muse, mutect2, varscan2
- FADS1 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 69/431 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs1044912550; called by muse, mutect2, varscan2
- FAM110D | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 95/585 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.825); catalogued as rs547943064; called by muse, mutect2, varscan2
- FAM160A1 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 71/486 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs770265826, COSV70707327; called by muse, mutect2, varscan2
- FAM166A | c.360A>G p.I120M | Missense Mutation (SNP) | VAF 84/581 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs774924193; called by muse, mutect2, varscan2
- FAM47C | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 68/479 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs782169860, COSV63727411; called by muse, varscan2
- FAM47C | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 78/481 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63725357; called by muse, varscan2
- FAM98A | c.522del p.K174Nfs*2 | Frame Shift Del (DEL) | VAF 17/127 reads (13%) | catalogued as rs1237814873; called by mutect2, varscan2
- FAT3 | c.11921G>A p.R3974Q | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.441); catalogued as rs182427205; called by muse, mutect2, varscan2
- FAT3 | c.12697C>T p.R4233C | Missense Mutation (SNP) | VAF 66/462 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760262852, COSV53100646, COSV53100654; called by muse, varscan2
- FBLIM1 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs776825526, COSV60028532; called by muse, mutect2, varscan2
- FBXO28 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 60/468 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs769544662, COSV100837509; called by muse, mutect2, varscan2
- FEM1A | c.998del p.G333Afs*31 | Frame Shift Del (DEL) | VAF 62/483 reads (13%) | catalogued as COSV54163812; called by mutect2, varscan2
- FGFR4 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs774524474; called by muse, mutect2, varscan2
- FLNC | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 69/550 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776362922, COSV57965274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNIP2 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs375103955; called by muse, varscan2
- FOXD2 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 109/650 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs774532525; called by muse, mutect2, varscan2
- FPR1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs764370052, COSV59050822; called by muse, varscan2
- FREM2 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs367642497; called by muse, mutect2, varscan2
- FRG1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs17425208; called by muse, varscan2
- FURIN | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs780282947, COSV51576777; called by muse, mutect2, varscan2
- FUT2 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 57/420 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226933974, COSV67179865; called by muse, mutect2, varscan2
- GALK1 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 69/500 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV52334102; called by muse, mutect2, varscan2
- GBF1 | c.825_827del p.S276del | In Frame Del (DEL) | VAF 42/323 reads (13%) | catalogued as rs776700772; called by pindel, varscan2
- GCN1 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs779673727; called by muse, mutect2, varscan2
- GDNF | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775157679; called by muse, mutect2, varscan2
- GDPD2 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100978550, COSV100978576; called by muse, mutect2
- GFRA1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 64/528 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs768000593, COSV100815612; called by muse, mutect2, varscan2
- GFRA2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 83/560 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as rs754540853, COSV60778478; called by muse, varscan2
- GGT5 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs762568060, COSV54070722, COSV54073048; called by muse, mutect2, varscan2
- GLIS1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs1162049796; called by muse, mutect2, varscan2
- GNAS | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 95/563 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as rs767898826, COSV58342186, COSV58342626; called by muse, mutect2, varscan2
- GOLPH3 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs760560885, COSV54059724; called by muse, mutect2, varscan2
- GPHA2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 41/393 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1357332620, COSV51209660; called by muse, mutect2, varscan2
- GPR12 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs934276305; called by muse, mutect2, varscan2
- GPR35 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 86/521 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60578017; called by muse, varscan2
- GPS1 | c.1279C>G p.R427G | Missense Mutation (SNP) | VAF 77/419 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100152410; called by muse, mutect2, varscan2
- GRIA3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 71/409 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV52049568; called by muse, mutect2, varscan2
- GRID2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); catalogued as rs1282591728, COSV56226121; called by muse, mutect2, varscan2
- GRN | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs747362041, CM128865, COSV50006335; called by muse, mutect2, varscan2
- GUCA2B | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575722051; called by muse, mutect2, varscan2
- GUCY2D | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 75/414 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV104369023; called by muse, mutect2, varscan2
- H3-3B | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 63/412 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV99638051; called by muse, mutect2, varscan2
- HAPLN2 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 82/519 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54815753; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 37/321 reads (12%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HCAR2 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 63/755 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as rs750950242; called by muse, mutect2
- HDX | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 47/418 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as rs755144914; called by muse, mutect2, varscan2
- HELB | c.1506dup p.A503Sfs*3 | Frame Shift Ins (INS) | VAF 42/345 reads (12%) | catalogued as rs772334560; called by mutect2, varscan2
- HERC6 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs370593928; called by muse, mutect2, varscan2
- HIPK2 | c.2688G>C p.E896D | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV61225630; called by muse, varscan2
- HMOX1 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 71/506 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781675840; called by muse, mutect2, varscan2
- HOATZ | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs757633014; called by muse, mutect2, varscan2
- HSPA1L | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 125/673 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as COSV65149390; called by muse, mutect2, varscan2
- HTR1A | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 99/513 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as COSV60500700; called by muse, mutect2, varscan2
- HTRA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 88/529 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs955773421; called by muse, mutect2, varscan2
- HTRA3 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs368872824, COSV56472754; called by muse, mutect2, varscan2
- HUWE1 | c.5972A>G p.Y1991C | Missense Mutation (SNP) | VAF 72/478 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV53358597; called by muse, mutect2, varscan2
- IGHJ4 | c.8A>G p.D3G | Missense Mutation (SNP) | VAF 47/343 reads (14%) | PolyPhen benign (0.1); catalogued as rs376281741; called by muse, mutect2, varscan2
- IGHJ6 | c.36del p.T14Pfs*? | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | catalogued as rs782069297; called by pindel, varscan2
- IGHV3OR15-7 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.67); catalogued as rs772855676; called by muse, mutect2, varscan2
- IGKV1D-8 | c.295T>A p.C99S | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774859063; called by muse, mutect2, varscan2
- IGKV4-1 | c.51T>C p.G17= | Splice Region (SNP) | VAF 28/220 reads (13%) | catalogued as rs1330548526; called by muse, mutect2, varscan2
- IMPACT | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); catalogued as rs766106939; called by muse, mutect2, varscan2
- INA | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 98/591 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as rs1288301696, COSV63976509; called by muse, mutect2, varscan2
- INS-IGF2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1184417816, COSV51748141; called by muse, mutect2
- IQCH | c.1950A>G p.I650M | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1297827084; called by muse, mutect2
- IQSEC2 | c.3206G>A p.R1069Q (on ENST00000642864 / NM_001111125.3; = p.R864Q on NM_015075.2) | Missense Mutation (SNP) | VAF 84/540 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs782632137, COSV64725358; called by muse, mutect2, varscan2
- IRF2BPL | c.261_263del p.A102del | In Frame Del (DEL) | VAF 31/144 reads (22%) | catalogued as rs761143271; called by mutect2, pindel, varscan2
- IRS2 | c.3272del p.P1091Rfs*15 | Frame Shift Del (DEL) | VAF 91/698 reads (13%) | catalogued as COSV65478769, COSV65480097; called by pindel, varscan2
- ITGB8 | c.*5del | Frame Shift Del (DEL) | VAF 30/180 reads (17%) | catalogued as rs770665724; called by mutect2, pindel, varscan2
- JMY | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 74/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68659240; called by muse, mutect2, varscan2
- JRKL | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1463807331; called by muse, mutect2, varscan2
- KAT6A | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1207862469, COSV55903922; called by muse, mutect2, varscan2
- KAT6B | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 55/540 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs768128984; called by muse, mutect2, varscan2
- KCND1 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782594666, COSV54415755; called by muse, mutect2, varscan2
- KCNK18 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 54/572 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs757078093, COSV57970575; called by muse, mutect2
- KCNU1 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101299315; called by muse, mutect2
- KDM5A | c.4259C>T p.P1420L | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV66992304, COSV66995054; called by muse, mutect2, varscan2
- KIAA0100 | c.5145T>A p.S1715R | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV66495265; called by muse, mutect2, varscan2
- KIAA2013 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 88/574 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.576); catalogued as rs752571487, COSV64860609; called by muse, mutect2, varscan2
- KIF18B | c.2135C>T p.P712L (on ENST00000593135 / NM_001265577.2; = p.P724L on NM_001264573.2) | Missense Mutation (SNP) | VAF 98/503 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs775362348, COSV100192102; called by muse, mutect2, varscan2
- KIF1C | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.171); catalogued as rs1347751013; called by muse, varscan2
- KIF26B | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 62/519 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs771134927; called by muse, mutect2, varscan2
- KIRREL1 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474957010; called by muse, mutect2, varscan2
- KLHL29 | c.2270C>T p.T757M | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs910594552; called by muse, mutect2, varscan2
- KMT2D | c.1016G>A p.W339* | Nonsense Mutation (SNP) | VAF 71/433 reads (16%) | catalogued as COSV56479912; called by muse, mutect2, varscan2
- KMT5B | c.1588del p.E530Rfs*8 | Frame Shift Del (DEL) | VAF 69/543 reads (13%) | catalogued as COSV58566563; called by mutect2, pindel, varscan2
- KNTC1 | c.930G>A p.T310= | Splice Region (SNP) | VAF 29/197 reads (15%) | catalogued as rs1219776941, COSV100338854; called by muse, varscan2
- KREMEN2 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 78/546 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754918639; called by muse, mutect2, varscan2
- KRT35 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs772155702; called by muse, mutect2, varscan2
- KRT4 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1260907872, COSV53406765; called by muse, mutect2, varscan2
- KRT71 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 76/535 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs532689963; called by muse, mutect2, varscan2
- KRTAP26-1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 85/471 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as rs767826058, COSV62128671; called by muse, mutect2, varscan2
- KRTAP4-3 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 78/534 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1278286994; called by muse, varscan2
- KY | c.198C>T p.H66= | Splice Region (SNP) | VAF 31/233 reads (13%) | catalogued as rs747530241, COSV71016755; called by muse, mutect2, varscan2
- L3MBTL4 | c.1438T>C p.F480L | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as rs777962167; called by muse, mutect2, varscan2
- LAMA5 | c.5614C>T p.R1872C | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs200431325; called by muse, mutect2, varscan2
- LAT | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs369317401; called by muse, mutect2, varscan2
- LCOR | c.2672G>A p.R891H | Missense Mutation (SNP) | VAF 45/382 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs141178994; called by muse, mutect2, varscan2
- LDLR | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768925824, COSV52946936; ClinVar: uncertain significance; called by muse, varscan2
- LHX8 | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.123); catalogued as COSV53955046; called by muse, mutect2, varscan2
- LIMCH1 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs571021758; called by muse, mutect2, varscan2
- LITAF | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 75/497 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs765644026, COSV59655532; ClinVar: likely benign; called by muse, mutect2, varscan2
- LONP1 | c.2266A>G p.M756V | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs754562604; called by muse, mutect2, varscan2
- LONRF3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 86/608 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs1422064808; called by mutect2, varscan2
- LORICRIN | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 105/726 reads (14%) | PolyPhen benign (0.007); catalogued as rs1292824108; called by mutect2, varscan2
- LOX | c.892A>G p.M298V | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1244036482; called by muse, mutect2, varscan2
- LOXHD1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 58/379 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397517861, COSV101492308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN1 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 100/588 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs1363116185; called by muse, varscan2
- LRP6 | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759239877, COSV104371948; called by muse, mutect2, varscan2
- LRRC45 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1361955053; called by muse, mutect2, varscan2
- LRRC4C | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV53421323; called by muse, mutect2, varscan2
- LRRC61 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs775492913; called by muse, mutect2, varscan2
- LRRC8B | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.802); catalogued as COSV58378013; called by muse, mutect2, varscan2
- LRRK2 | c.5870G>T p.R1957L | Missense Mutation (SNP) | VAF 57/355 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.635); catalogued as rs201012950, COSV54166940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRN4 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.485); catalogued as rs1265122696, COSV66644516; called by muse, mutect2, varscan2
- LRSAM1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); catalogued as rs200115008; called by muse, mutect2, varscan2
- LTBP4 | c.2272C>T p.R758* (on ENST00000308370 / NM_001042544.1; = p.R721* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 36/355 reads (10%) | catalogued as rs1377226312; called by muse, mutect2, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 37/293 reads (13%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- MAGEA12 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 78/554 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1556833500, COSV100757013, COSV63295146; called by muse, mutect2, varscan2
- MAGEA4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 57/493 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV99367195; called by muse, mutect2, varscan2
- MALRD1 | c.5493A>C p.E1831D | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV104426014; called by muse, mutect2, varscan2
- MANEAL | c.219_224del p.P74_P75del | In Frame Del (DEL) | VAF 36/190 reads (19%) | catalogued as rs878984290; called by mutect2, varscan2
- MAP1A | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 67/422 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1351291829; called by muse, mutect2, varscan2
- MAP2K2 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 66/444 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs756416031; called by muse, mutect2, varscan2
- MAP3K21 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759521299, COSV100786190; called by muse, varscan2
- MAP7D3 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371634445, COSV60170410; called by muse, mutect2, varscan2
- MAPK8IP1 | c.658del p.Q220Rfs*56 | Frame Shift Del (DEL) | VAF 75/541 reads (14%) | catalogued as rs781009214; called by mutect2, pindel, varscan2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 56/436 reads (13%) | catalogued as rs748185381; called by mutect2, pindel, varscan2
- MCCC1 | c.1724G>A p.S575N | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs886058206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MDM4 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 69/434 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs997328622; called by muse, mutect2, varscan2
- MDN1 | c.10169A>G p.Y3390C | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV101021949; called by muse, mutect2, varscan2
- MEF2C | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.949); catalogued as rs749895889, COSV60924865; called by muse, mutect2, varscan2
- MFSD8 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs375681665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MGAM2 | c.3241C>T p.R1081C | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907904679; called by muse, mutect2, varscan2
- MGAT5B | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs758394238, COSV56927170; called by muse, mutect2, varscan2
- MID2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 89/504 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs778859599; ClinVar: uncertain significance; called by muse, varscan2
- MINDY3 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53218095; called by muse, mutect2
- MKRN1 | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs769326339; called by muse, mutect2, varscan2
- MMP16 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs770249742; called by muse, mutect2, varscan2
- MMP28 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1195215320; called by muse, mutect2, varscan2
- MOAP1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375914261, COSV52092142; called by muse, mutect2
- MORF4L2 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 81/441 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV64611007; called by muse, mutect2, varscan2
- MPP7 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs35450618; called by muse, mutect2, varscan2
- MSC | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 95/648 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57696919; called by muse, mutect2, varscan2
- MSX1 | c.485del p.P162Qfs*55 | Frame Shift Del (DEL) | VAF 47/366 reads (13%) | catalogued as rs762477502; called by mutect2, pindel, varscan2
- MTCL1 | c.4327C>T p.H1443Y (on ENST00000306329 / NM_001378206.1; = p.H1124Y on NM_015210.4) | Missense Mutation (SNP) | VAF 70/539 reads (13%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.713); catalogued as rs751107786; called by muse, mutect2, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 35/260 reads (13%) | catalogued as rs761538540; called by mutect2, pindel, varscan2
- MTMR7 | c.1559A>G p.Y520C | Missense Mutation (SNP) | VAF 58/446 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV51670044; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 70/480 reads (15%) | catalogued as rs765184193; called by pindel, varscan2
- MUSK | c.581dup p.N194Kfs*16 | Frame Shift Ins (INS) | VAF 47/413 reads (11%) | catalogued as rs1395885868; called by mutect2, pindel, varscan2
- MYBPC2 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1387947267, COSV63093953; called by muse, mutect2, varscan2
- MYCN | c.134dup p.E47Gfs*8 | Frame Shift Ins (INS) | VAF 69/606 reads (11%) | catalogued as rs780080562; called by mutect2, varscan2
- MYH1 | c.5353C>T p.R1785W | Missense Mutation (SNP) | VAF 47/431 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139004562; called by muse, mutect2, varscan2
- MYH4 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs377612250; called by muse, mutect2, varscan2
- MYH9 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337911; called by muse, mutect2, varscan2
- MYO10 | c.3666del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 67/472 reads (14%) | catalogued as COSV57024246; called by mutect2, pindel, varscan2
- MYO18A | c.4721G>A p.R1574H | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772761503, COSV62867437; called by muse, mutect2, varscan2
- MYO7A | c.3857C>T p.A1286V | Missense Mutation (SNP) | VAF 54/542 reads (10%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.994); catalogued as rs575475444; called by muse, mutect2
- MZF1 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 113/772 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs190254725; called by muse, mutect2, varscan2
- NAGA | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs1430376455; called by muse, mutect2, varscan2
- NBEA | c.7880A>C p.N2627T | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV59780304; called by muse, mutect2, varscan2
- NCAPD2 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778834087, COSV59698112; called by muse, mutect2, varscan2
- NCKAP5L | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 79/554 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs761547348; called by muse, mutect2, varscan2
- NCOR2 | c.7312C>T p.R2438C | Missense Mutation (SNP) | VAF 35/606 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369730227; called by muse, mutect2
- NDUFAF6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 63/497 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1332553533; called by muse, mutect2, varscan2
- NECTIN3 | c.1117dup p.R373Kfs*6 | Frame Shift Ins (INS) | VAF 40/291 reads (14%) | catalogued as rs761400350; called by mutect2, varscan2
- NEDD9 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as rs371491128, COSV104432500; called by muse, mutect2, varscan2
- NES | c.3751G>T p.G1251W | Missense Mutation (SNP) | VAF 29/571 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100957780; called by muse, mutect2
- NEURL4 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 76/749 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.799); catalogued as rs749790370; called by muse, mutect2
- NEXN | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746761862; called by muse, mutect2, varscan2
- NIPBL | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as rs1402389849; called by muse, mutect2
- NKX6-2 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 81/662 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs941764422; called by muse, mutect2, varscan2
- NLGN4X | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 66/429 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs746531523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 29/224 reads (13%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NOD1 | c.2756C>T p.A919V | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs756787306; called by muse, mutect2, varscan2
- NOMO1 | c.3444G>A p.T1148= | Splice Region (SNP) | VAF 43/214 reads (20%) | catalogued as rs201319907; called by muse, mutect2, varscan2
- NOS1 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57616988; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 63/335 reads (19%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH3 | c.6932C>T p.P2311L | Missense Mutation (SNP) | VAF 42/379 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs771682246, COSV99655690; called by mutect2, varscan2
- NPC1L1 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755881757, CM068042, COSV99202550; called by muse, mutect2, varscan2
- NPHS1 | c.2227C>A p.R743S | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as CD101341, CM990965, COSV62289280; called by muse, mutect2
- NPTXR | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1286301565; called by muse, mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 27/228 reads (12%) | catalogued as rs1167519601; called by mutect2, pindel, varscan2
- NRG2 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769231072, COSV99180262; called by muse, mutect2, varscan2
- NRN1L | c.31T>C p.C11R | Missense Mutation (SNP) | VAF 80/464 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs771645336; called by muse, mutect2, varscan2
- NRXN2 | c.1826C>T p.T609M | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); catalogued as rs771232556; called by muse, mutect2, varscan2
- NRXN2 | c.808del p.A270Pfs*57 | Frame Shift Del (DEL) | VAF 41/346 reads (12%) | catalogued as rs754860965; called by mutect2, varscan2
- NUP214 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs371986910; called by muse, mutect2, varscan2
- NUP93 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771130377, COSV57428419; called by muse, mutect2, varscan2
- OAS3 | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370043042; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 106/568 reads (19%) | catalogued as rs762005098; called by mutect2, varscan2
- OGDHL | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 62/508 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs148413282, COSV65104158; called by muse, varscan2
- OGDHL | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 59/483 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100934237; called by muse, mutect2, varscan2
- OR13A1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 77/649 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs763621429, COSV65572174; called by muse, mutect2, varscan2
- OR4N2 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs770714683; called by muse, mutect2, varscan2
- OR4X1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as rs568260658, COSV100186677, COSV60723069; called by muse, varscan2
- OR51G1 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111446872; called by muse, mutect2, varscan2
- OR5V1 | c.271del p.S91Afs*18 | Frame Shift Del (DEL) | VAF 57/399 reads (14%) | catalogued as rs754676491; called by mutect2, varscan2
- OR6Y1 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV56929837; called by muse, mutect2
- OTUD7B | c.366del p.S123Afs*29 | Frame Shift Del (DEL) | VAF 52/393 reads (13%) | catalogued as rs1553776851; called by mutect2, pindel, varscan2
- OXTR | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 55/433 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1244817296, COSV57478421, COSV57479410; called by muse, mutect2, varscan2
- PAPLN | c.2408G>A p.S803N (on ENST00000554301; = p.S776N on NM_173462.4) | Missense Mutation (SNP) | VAF 83/544 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs548947330, COSV53718918; called by muse, mutect2, varscan2
- PAPOLA | c.275del p.N92Mfs*14 | Frame Shift Del (DEL) | VAF 22/201 reads (11%) | catalogued as COSV53479413; called by mutect2, pindel, varscan2
- PARD6G | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 72/660 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.17); catalogued as rs1243809706; called by muse, mutect2, varscan2
- PARP1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 78/444 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs369900729; called by muse, mutect2, varscan2
- PARP9 | c.337del p.M113Cfs*2 | Frame Shift Del (DEL) | VAF 56/447 reads (13%) | catalogued as COSV100831321; called by mutect2, pindel, varscan2
- PARS2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs879231179, COSV64883672; called by muse, mutect2, varscan2
- PCDH8 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 75/509 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (1); catalogued as COSV58813297, COSV58813836; called by muse, mutect2, varscan2
- PCDHA11 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 59/434 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as rs1554164932, COSV56530230; called by muse, mutect2, varscan2
- PCDHA12 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 106/604 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs781787046, COSV56485542; called by muse, mutect2, varscan2
- PCDHA3 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 114/745 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV63540052; called by muse, mutect2, varscan2
- PCDHGA11 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1287891140, COSV99543596; called by muse, mutect2, varscan2
- PCSK4 | c.1547C>T p.T516M | Missense Mutation (SNP) | VAF 77/461 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771978431, COSV56300290; called by muse, mutect2, varscan2
- PDCL | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV52343419; called by muse, mutect2
- PDZD7 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 112/803 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs769641288; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 66/372 reads (18%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKA2 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.135); catalogued as COSV101177456; called by muse, mutect2, varscan2
- PIK3C2A | c.3593T>C p.V1198A | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1430665356; called by muse, mutect2, varscan2
- PIK3CD | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 57/476 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as rs767750196, COSV63128285; called by muse, mutect2, varscan2
- PITPNM3 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 59/448 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs769380932, COSV99337935, COSV99338042; called by muse, mutect2
- PKD1 | c.8776T>C p.Y2926H | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as CD1110573; called by muse, mutect2
- PLEKHG4B | c.1547C>T p.A516V (on ENST00000283426; = p.A872V on NM_052909.5) | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs370764339, COSV99360937; called by muse, mutect2, varscan2
- PLEKHM2 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 78/515 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV65396389; called by muse, mutect2, varscan2
- PLIN2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs769414908, COSV99439110; called by muse, mutect2
- PLIN4 | c.4060G>A p.A1354T (on ENST00000301286; = p.A1369T on NM_001367868.2) | Missense Mutation (SNP) | VAF 39/404 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs773116537; called by muse, mutect2
- PLPPR5 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 55/527 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99587499; called by muse, mutect2, varscan2
- PLXNA4 | c.4823T>C p.V1608A | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1218309320; called by muse, mutect2, varscan2
- PLXNB3 | c.3487C>T p.R1163C | Missense Mutation (SNP) | VAF 80/651 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1485879456; called by muse, mutect2
- PNCK | c.633del p.F212Sfs*14 (on ENST00000340888 / NM_001366975.1; = p.F295Sfs*14 on NM_001039582.3) | Frame Shift Del (DEL) | VAF 54/449 reads (12%) | catalogued as rs781891121, COSV61745231; called by mutect2, pindel, varscan2
- POSTN | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.901); catalogued as rs953629256; called by muse, mutect2, varscan2
- POTEE | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 100/1362 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.911); catalogued as rs1210200393, COSV100388222; called by muse, mutect2
- PPARD | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.23); catalogued as rs141397262; called by muse, mutect2, varscan2
- PPM1J | c.237del p.L80Cfs*102 | Frame Shift Del (DEL) | VAF 78/569 reads (14%) | catalogued as rs1553190966; called by mutect2, pindel, varscan2
- PPP1R3C | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303503889; called by muse, mutect2, varscan2
- PPP3R2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 71/550 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs746497872, COSV62452747; called by muse, mutect2, varscan2
- PRDM15 | c.2196G>T p.K732N | Missense Mutation (SNP) | VAF 52/432 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54153949; called by muse, mutect2, varscan2
- PRDM2 | c.4773del p.K1591Nfs*23 | Frame Shift Del (DEL) | VAF 71/446 reads (16%) | catalogued as rs1435057935, COSV52454422; called by mutect2, pindel, varscan2
- PRIM1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs373368001; called by muse, mutect2, varscan2
- PRLHR | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 63/546 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766960234, COSV53302959; called by muse, varscan2
- PROS1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as rs754518511; called by muse, mutect2, varscan2
- PROX1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs112763420; called by muse, mutect2, varscan2
- PRRT2 | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 34/644 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.159); catalogued as COSV99569240; called by muse, mutect2
- PTBP1 | c.1386G>A p.P462= (on ENST00000349038 / NM_031991.4; = p.P488= on NM_002819.5) | Splice Region (SNP) | VAF 38/316 reads (12%) | catalogued as rs140316841; called by muse, mutect2, varscan2
- PTPRN | c.2002A>G p.S668G | Missense Mutation (SNP) | VAF 70/583 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1163673886; called by muse, mutect2, varscan2
- PTX3 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs917212503; called by muse, mutect2, varscan2
- PVR | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 89/525 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs753294991; called by muse, mutect2, varscan2
- RAB11A | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 64/353 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV56041501; called by muse, mutect2, varscan2
- RALGAPB | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs909701420, COSV99485046; called by muse, mutect2, varscan2
- RBBP4 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV65132303; called by muse, varscan2
- RBL1 | c.2876A>C p.D959A | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV100726942; called by muse, mutect2
- RBP3 | c.1510G>A p.V504M | Missense Mutation (SNP) | VAF 84/636 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); catalogued as rs782543571; called by muse, mutect2, varscan2
- RCC1 | c.38del p.P13Qfs*11 | Frame Shift Del (DEL) | VAF 65/384 reads (17%) | catalogued as rs746656171; called by mutect2, varscan2
- RCOR2 | c.1492dup p.R498Pfs*58 | Frame Shift Ins (INS) | VAF 32/274 reads (12%) | catalogued as rs1226030398; called by mutect2, pindel, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 44/305 reads (14%) | catalogued as COSV100563010; called by mutect2, pindel, varscan2
- REPIN1 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 114/728 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs1309383284; called by muse, mutect2
- RETREG3 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755968915; called by muse, mutect2, varscan2
- REV1 | c.160A>G p.I54V | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs757987656; called by muse, mutect2, varscan2
- RINL | c.1576G>A p.A526T (on ENST00000591812 / NM_001195833.2; = p.A412T on NM_198445.4) | Missense Mutation (SNP) | VAF 88/528 reads (17%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.92); catalogued as rs1441299731; called by muse, mutect2, varscan2
- RIPK4 | c.1321C>T p.R441W (on ENST00000352483; = p.R393W on NM_020639.3) | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs141192148; called by muse, mutect2, varscan2
- RNF111 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 60/372 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs769030367; called by muse, mutect2, varscan2
- RNF144A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV57983305; called by muse, mutect2, varscan2
- RNF180 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV56965693; called by muse, mutect2, varscan2
- RNF19B | c.2059T>C p.S687P | Missense Mutation (SNP) | VAF 64/464 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV52386936; called by muse, varscan2
- RNF222 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 99/541 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs1219281529; called by muse, mutect2, varscan2
- RNF224 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 75/534 reads (14%) | SIFT deleterious, low confidence (0); catalogued as rs1046352284; called by muse, mutect2, varscan2
- RNF224 | c.48dup p.P17Afs*16 | Frame Shift Ins (INS) | VAF 66/590 reads (11%) | catalogued as rs764684501; called by mutect2, pindel, varscan2
- RNPC3 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs772573445; called by muse, mutect2, varscan2
- RNPEPL1 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs867370126, COSV54373545; called by muse, mutect2, varscan2
- ROCK1 | c.2612del p.N871Tfs*5 | Frame Shift Del (DEL) | VAF 22/194 reads (11%) | catalogued as COSV67695859; called by mutect2, pindel, varscan2
- RORC | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59095739; called by muse, mutect2, varscan2
- ROS1 | c.1087dup p.Y363Lfs*25 | Frame Shift Ins (INS) | VAF 29/319 reads (9%) | catalogued as rs1392239785; called by mutect2, pindel
- RP1L1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 58/480 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs781222519; called by muse, mutect2, varscan2
- RSPH14 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs556605808, COSV53272397; called by muse, mutect2, varscan2
- RUNX3 | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 61/399 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1192925649; called by muse, mutect2, varscan2
- SALL3 | c.906del p.G303Afs*92 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs1424702195; called by mutect2, pindel, varscan2
- SALL3 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 97/683 reads (14%) | catalogued as rs751879304, COSV101609972; called by muse, mutect2, varscan2
- SARDH | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 83/550 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758532734; called by muse, mutect2, varscan2
- SCGN | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs769675702; called by muse, mutect2, varscan2
- SCTR | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs143548648; called by muse, mutect2, varscan2
- SEL1L3 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201744798; called by muse, mutect2, varscan2
- SERPINA3 | c.350A>G p.Q117R | Missense Mutation (SNP) | VAF 78/459 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as rs1219409865; called by muse, mutect2, varscan2
- SETD5 | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 31/237 reads (13%) | catalogued as COSV100200794; called by muse, mutect2, varscan2
- SETDB1 | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs756236845; called by muse, mutect2, varscan2
- SETDB2 | c.2152del p.I718Yfs*11 | Frame Shift Del (DEL) | VAF 31/162 reads (19%) | catalogued as rs775302281, COSV57902985; called by mutect2, varscan2
- SETX | c.6114_6115del p.C2038Wfs*15 | Frame Shift Del (DEL) | VAF 21/226 reads (9%) | catalogued as rs1256537236; called by pindel, varscan2
- SF3B4 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54965341; called by muse, mutect2, varscan2
- SFMBT2 | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 85/656 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs147695246, COSV62817861; called by muse, mutect2, varscan2
- SFMBT2 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV100738574; called by muse, mutect2, varscan2
- SFXN5 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985878534; called by muse, mutect2, varscan2
- SGMS1 | c.282del p.D95Tfs*21 | Frame Shift Del (DEL) | VAF 69/539 reads (13%) | catalogued as COSV62370464; called by mutect2, pindel, varscan2
- SGSH | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs769633955, COSV58339965; called by muse, mutect2, varscan2
- SH3TC1 | c.3301C>A p.L1101M | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs1331829250; called by muse, mutect2
- SHE | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 96/659 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV59070813; called by muse, mutect2, varscan2
- SHH | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 107/635 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1306061587; called by muse, mutect2, varscan2
- SIGLEC1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 93/576 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs750829302; called by muse, mutect2, varscan2
- SIRT4 | c.538del p.V180Cfs*9 | Frame Shift Del (DEL) | VAF 59/437 reads (14%) | catalogued as COSV52540289, COSV52541732; called by mutect2, pindel, varscan2
- SLC14A2 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV54907778; called by muse, mutect2, varscan2
- SLC16A11 | c.1164del p.L389Sfs*10 (on ENST00000308009; = p.L365Sfs*10 on NM_153357.3) | Frame Shift Del (DEL) | VAF 72/432 reads (17%) | catalogued as rs770453216; called by mutect2, varscan2
- SLC19A3 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as COSV51454193; called by muse, mutect2
- SLC25A23 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1367028808, COSV99902594; called by muse, varscan2
- SLC26A11 | c.1552T>C p.C518R | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780788573; called by muse, mutect2
- SLC2A6 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 78/569 reads (14%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.999); catalogued as rs782634173, COSV52469607; called by muse, mutect2, varscan2
- SLC2A9 | c.537C>T p.G179= | Splice Region (SNP) | VAF 36/290 reads (12%) | catalogued as rs753136929, COSV53330367, COSV53330844; called by muse, mutect2
- SLC30A3 | c.613del p.H205Tfs*260 | Frame Shift Del (DEL) | VAF 66/454 reads (15%) | catalogued as rs745429257; called by pindel, varscan2
- SLC34A3 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 62/584 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as rs376991926; called by muse, mutect2, varscan2
- SLC35B2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 72/509 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as rs144120153; called by muse, mutect2, varscan2
- SLC35E4 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs766424419, COSV55898627; called by muse, mutect2, varscan2
- SLC37A2 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs535796071, COSV53520187; called by muse, mutect2, varscan2
- SLC39A2 | c.709del p.L237Wfs*3 | Frame Shift Del (DEL) | VAF 82/518 reads (16%) | catalogued as COSV100068749; called by mutect2, pindel, varscan2
- SLC39A9 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV50363538; called by muse, mutect2, varscan2
- SLC5A10 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185855888, COSV100525322; called by muse, mutect2, varscan2
- SLC5A5 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 78/616 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs757127440; called by muse, mutect2, varscan2
- SLC6A8 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1211713, COSV53472014, COSV53472263; called by muse, mutect2, varscan2
- SLCO2B1 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV56940381; called by muse, mutect2, varscan2
- SLITRK1 | c.1296C>A p.S432R | Missense Mutation (SNP) | VAF 78/459 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV65677485; called by muse, mutect2, varscan2
- SLITRK1 | c.134del p.K45Rfs*64 | Frame Shift Del (DEL) | VAF 51/308 reads (17%) | catalogued as COSV65676896; called by mutect2, pindel, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 80/325 reads (25%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel, varscan2
- SMIM10L2B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 89/485 reads (18%) | SIFT tolerated (0.13); catalogued as rs1259623312; called by muse, mutect2, varscan2
- SMPD4 | c.1613G>A p.R538H (on ENST00000409031 / NM_017951.4; = p.R509H on NM_017751.4) | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1325049882, COSV99045471; called by muse, mutect2, varscan2
- SNCAIP | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 63/389 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1166376114; called by muse, mutect2, varscan2
- SNRPA1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs753401813; called by muse, mutect2, varscan2
- SNTB1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 66/471 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs753118124, COSV67324556; called by muse, mutect2, varscan2
- SNX18 | c.282del p.A95Pfs*131 | Frame Shift Del (DEL) | VAF 81/604 reads (13%) | catalogued as rs1473083188; called by mutect2, varscan2
- SNX32 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV57656492; called by muse, varscan2
- SOBP | c.1753del p.R585Gfs*22 | Frame Shift Del (DEL) | VAF 87/610 reads (14%) | catalogued as rs1554190709, COSV58003572; called by mutect2, pindel, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 35/263 reads (13%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SORCS3 | c.2940G>T p.Q980H | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63794786, COSV63796067; called by muse, mutect2, varscan2
- SOX10 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 48/754 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as COSV100704208; called by muse, mutect2
- SOX11 | c.1148del p.G383Afs*39 | Frame Shift Del (DEL) | VAF 74/518 reads (14%) | catalogued as rs1553328038; called by mutect2, varscan2
- SOX21 | c.663del p.H222Tfs*14 | Frame Shift Del (DEL) | VAF 20/172 reads (12%) | catalogued as rs1274977161; called by mutect2, pindel
- SOX7 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409142170, COSV100448991; called by muse, mutect2
- SPART | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.4); catalogued as COSV62087239; called by muse, mutect2, varscan2
- SPEM2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 80/552 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.872); catalogued as rs1342856745, COSV60367817; called by mutect2, varscan2
- SPINK8 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs371813695; called by muse, mutect2, varscan2
- SPNS1 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs765114982; called by muse, mutect2, varscan2
- SPNS3 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746083299, COSV61069966, COSV61072712; called by muse, mutect2, varscan2
- SRGAP2 | c.1933C>T p.P645S (on ENST00000624873 / NM_001170637.4; = p.P646S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99833435; called by muse, mutect2
- SRGAP2 | c.2785A>G p.S929G (on ENST00000624873 / NM_001170637.4; = p.S930G on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.012); catalogued as COSV55334139; called by muse, mutect2, varscan2
- SRRM2 | c.2519_2521del p.P840del | In Frame Del (DEL) | VAF 60/438 reads (14%) | catalogued as rs1460562808; called by pindel, varscan2
- SSBP4 | c.378del p.G127Afs*13 | Frame Shift Del (DEL) | VAF 24/123 reads (20%) | catalogued as rs760883618; called by mutect2, pindel, varscan2
- SSR4 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 64/481 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.941); catalogued as rs781990201, COSV51249792, COSV51253659; called by muse, mutect2, varscan2
- SSX2IP | c.546del p.K182Nfs*17 | Frame Shift Del (DEL) | VAF 16/162 reads (10%) | catalogued as rs1164558054; called by mutect2, pindel, varscan2
- STARD3 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs775353741; called by muse, mutect2, varscan2
- STOX2 | c.795del p.K265Nfs*4 | Frame Shift Del (DEL) | VAF 52/373 reads (14%) | catalogued as rs1456318764, COSV57849231; called by mutect2, pindel, varscan2
- STRA6 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as rs756683650; called by muse, varscan2
- STRN | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs759948480, COSV55747023; called by muse, mutect2, varscan2
- SYCP1 | c.2642del p.K881Rfs*21 | Frame Shift Del (DEL) | VAF 23/188 reads (12%) | catalogued as rs776683356; called by mutect2, varscan2
- SYTL3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 49/786 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs763358676, COSV51910656; called by muse, mutect2
- TAOK2 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 80/473 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs777936445, COSV54233021, COSV99663698; called by muse, mutect2, varscan2
- TBC1D4 | c.2791C>A p.L931M | Missense Mutation (SNP) | VAF 38/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66491265; called by muse, mutect2, varscan2
- TBK1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1511066; called by muse, mutect2, varscan2
- TBX19 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs776790291, COSV63198643; called by muse, mutect2, varscan2
- TBX4 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 69/592 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.299); catalogued as rs767623150, COSV53606301; called by muse, mutect2, varscan2
- TBXA2R | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 93/529 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1390964033; called by muse, mutect2, varscan2
- TCEAL4 | c.391A>G p.N131D | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.228); catalogued as rs1486224426; called by muse, mutect2
- TCEAL5 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 82/594 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs971265296; called by muse, mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 48/390 reads (12%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- TCOF1 | c.4388del p.K1463Rfs*112 (on ENST00000377797 / NM_001135243.1; = p.K1386Rfs*112 on NM_000356.4) | Frame Shift Del (DEL) | VAF 50/321 reads (16%) | catalogued as rs1316962237; called by mutect2, pindel, varscan2
- TEDC1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs983489160; called by muse, mutect2, varscan2
- TGIF2 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 68/428 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as rs777710225, COSV65836911; called by muse, mutect2, varscan2
- TICRR | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV51547620; called by muse, mutect2, varscan2
- TLE1 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs201140985; called by muse, mutect2
- TLN2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750791867, COSV60887439; called by muse, mutect2, varscan2
- TMEM132C | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 75/529 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.341); catalogued as COSV70656751; called by muse, mutect2, varscan2
- TMEM187 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 82/735 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1557122664; called by muse, mutect2, varscan2
- TMEM196 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1431131190; called by muse, mutect2, varscan2
- TMEM200C | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 63/509 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV67309230; called by muse, mutect2, varscan2
- TNFSF9 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 86/588 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763608575; called by muse, mutect2, varscan2
- TNKS1BP1 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 85/553 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1423481285; called by muse, mutect2, varscan2
- TNNI1 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 42/341 reads (12%) | catalogued as rs1159048123; called by muse, mutect2, varscan2
- TPBGL | c.1025A>C p.E342A | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1410830166; called by muse, mutect2, varscan2
- TPGS1 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1397778397; called by muse, mutect2, varscan2
- TPRN | c.994A>G p.M332V | Missense Mutation (SNP) | VAF 58/744 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751092269; called by muse, mutect2
- TRAF2 | c.26dup p.G10Wfs*70 | Frame Shift Ins (INS) | VAF 58/356 reads (16%) | catalogued as rs748531430; called by mutect2, varscan2
- TRERF1 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 84/513 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1339898470; called by muse, mutect2, varscan2
- TRIP6 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.603); catalogued as rs1187910144, COSV99566894; called by muse, mutect2, varscan2
- TRMT44 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs527965244; called by muse, mutect2, varscan2
- TRPC1 | c.1545del p.F515Lfs*41 (on ENST00000476941 / NM_001251845.2; = p.F481Lfs*41 on NM_003304.4) | Frame Shift Del (DEL) | VAF 30/333 reads (9%) | catalogued as rs1214691323, COSV99858337; called by mutect2, pindel
- TRPM2 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 80/523 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs753183141, COSV55969425; called by muse, mutect2, varscan2
- TRPV2 | c.1244T>G p.L415R | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV58429098; called by mutect2, varscan2
- TRRAP | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782796108; called by muse, mutect2, varscan2
- TSC2 | c.921C>G p.H307Q | Missense Mutation (SNP) | VAF 58/404 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs878854121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC14 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1392237646; called by muse, varscan2
- TTC26 | c.718G>C p.A240P | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.502); catalogued as COSV58272148; called by muse, mutect2, varscan2
- TTN | c.15106C>A p.R5036= (on ENST00000591111; = p.R4109= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 42/256 reads (16%) | catalogued as rs267599069, COSV59961885; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TXLNG | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 95/582 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1357428724; called by muse, mutect2, varscan2
- TXN2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776811065, COSV53397825; called by muse, mutect2, varscan2
- TYRP1 | c.1200del p.F400Lfs*16 | Frame Shift Del (DEL) | VAF 52/423 reads (12%) | catalogued as rs1563856255; called by mutect2, pindel, varscan2
- TYW5 | c.576T>C p.G192= | Splice Region (SNP) | VAF 14/134 reads (10%) | catalogued as COSV63562512; called by muse, varscan2
- UBE4B | c.2636C>T p.A879V (on ENST00000343090 / NM_001105562.3; = p.A750V on NM_006048.5) | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs770338844, COSV99477144; called by muse, varscan2
- UBXN11 | c.824G>A p.R275Q (on ENST00000374221 / NM_183008.2; = p.R242Q on NM_145345.2) | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1256557524; called by muse, mutect2, varscan2
- UNC45A | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 89/544 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.133); catalogued as rs776603989, COSV101265730; called by muse, mutect2, varscan2
- UNC5CL | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 72/505 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs149219001; called by muse, mutect2, varscan2
- UNC80 | c.8834C>T p.T2945M | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1475238797, COSV55913284; called by muse, mutect2, varscan2
- USP36 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs759229493, COSV61751915; called by muse, mutect2, varscan2
- USP6NL | c.1651T>C p.Y551H | Missense Mutation (SNP) | VAF 84/578 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104375016; called by muse, mutect2, varscan2
- UTP20 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.203); catalogued as rs548791318, COSV55386500; called by muse, varscan2
- VAMP2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 74/556 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1246190856; called by muse, mutect2, varscan2
- VANGL2 | c.801-1G>T p.X267_splice | Splice Site (SNP) | VAF 27/182 reads (15%) | catalogued as COSV100925561; called by mutect2, varscan2
- VPS11 | c.578A>G p.Y193C (on ENST00000620429; = p.Y737C on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/430 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as rs1322232478; called by muse, mutect2, varscan2
- VPS13B | c.11509C>T p.R3837C | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs369891888; called by muse, mutect2, varscan2
- VWC2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs780603854, COSV61486679; called by muse, mutect2, varscan2
- WDR24 | c.2741G>A p.G914D (on ENST00000248142; = p.G784D on NM_032259.4) | Missense Mutation (SNP) | VAF 62/425 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768793717; called by muse, mutect2, varscan2
- WDR61 | c.7A>G p.N3D | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs1370861922; called by muse, mutect2
- WDR81 | c.4643del p.G1548Afs*55 (on ENST00000409644 / NM_001163809.2; = p.G497Afs*55 on NM_152348.4) | Frame Shift Del (DEL) | VAF 111/761 reads (15%) | catalogued as COSV58483581; called by mutect2, pindel, varscan2
- WDR97 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 115/765 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100075971; called by muse, mutect2, varscan2
- WFIKKN1 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 90/556 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs761037038; called by muse, mutect2, varscan2
- WIZ | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs774556910; called by muse, mutect2, varscan2
- WNT5A | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 90/530 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1559553986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WT1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs749266841, COSV60086824, COSV60087202; called by muse, mutect2, varscan2
- XRCC3 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs749394060; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 96/502 reads (19%) | catalogued as rs779864368; called by mutect2, varscan2
- ZCCHC2 | c.3222del p.L1075Cfs*42 | Frame Shift Del (DEL) | VAF 49/329 reads (15%) | catalogued as rs1205072403; called by mutect2, pindel, varscan2
- ZCCHC24 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 70/545 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64886408; called by muse, mutect2, varscan2
- ZFAND4 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 63/473 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs770140461; called by muse, mutect2, varscan2
- ZFHX2 | c.3802C>T p.R1268W | Missense Mutation (SNP) | VAF 70/479 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1298732601; called by muse, mutect2, varscan2
- ZIC1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 108/687 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99031826; called by muse, mutect2, varscan2
- ZNF14 | c.971C>A p.A324E | Missense Mutation (SNP) | VAF 74/456 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as rs563989129; called by muse, mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 68/524 reads (13%) | catalogued as rs751589999; called by mutect2, pindel, varscan2
- ZNF229 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 72/491 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.399); catalogued as rs907144421, COSV52162819; called by muse, mutect2, varscan2
- ZNF236 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772367977; called by muse, mutect2, varscan2
- ZNF251 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 46/692 reads (7%) | catalogued as rs755238061, COSV99478671; called by muse, mutect2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 31/198 reads (16%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF391 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.608); catalogued as rs777522196, COSV55122226; called by muse, mutect2, varscan2
- ZNF415 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769109320, COSV54698902; called by muse, varscan2
- ZNF423 | c.2924G>A p.R975H (on ENST00000563137 / NM_001379286.1; = p.R967H on NM_015069.4) | Missense Mutation (SNP) | VAF 69/466 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs771703239, COSV52190092; called by muse, mutect2, varscan2
- ZNF428 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 102/652 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.923); catalogued as rs376246653, COSV100334829; called by muse, mutect2, varscan2
- ZNF469 | c.10574C>T p.P3525L (on ENST00000437464; = p.P3553L on NM_001367624.2) | Missense Mutation (SNP) | VAF 97/586 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as rs1037365587; called by muse, mutect2, varscan2
- ZNF488 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 89/734 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs782681733; called by muse, mutect2, varscan2
- ZNF513 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 122/668 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52010033; called by muse, mutect2, varscan2
- ZNF600 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 85/414 reads (21%) | catalogued as rs1271995483; called by muse, mutect2, varscan2
- ZNF613 | c.965G>T p.G322V (on ENST00000293471 / NM_001031721.4; = p.G286V on NM_024840.4) | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53271143; called by muse, mutect2
- ZNF648 | c.1501del p.E501Rfs*116 | Frame Shift Del (DEL) | VAF 96/592 reads (16%) | catalogued as COSV60572766; called by mutect2, pindel, varscan2
- ZNF682 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 42/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1043435219, COSV62068447; called by muse, mutect2, varscan2
- ZNF723 | c.1424A>G p.H475R | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1266163761; called by muse, mutect2, varscan2
- ZNF786 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 94/542 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60277667; called by muse, varscan2
- ZNF814 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 75/469 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs759665175, COSV101457315; called by muse, mutect2, varscan2
- ZNFX1 | c.2165T>C p.M722T | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1480801147; called by muse, mutect2, varscan2
- ZNHIT6 | c.890del p.L297* | Frame Shift Del (DEL) | VAF 27/212 reads (13%) | catalogued as rs761793124; called by pindel, varscan2
- ZNHIT6 | c.556_558del p.K186del | In Frame Del (DEL) | VAF 57/387 reads (15%) | catalogued as rs1325248729; called by mutect2, pindel, varscan2
- ZXDA | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 121/723 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.388); catalogued as COSV62388468; called by muse, mutect2, varscan2
- AARD | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 98/696 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.074); called by muse, varscan2
- ABCA2 | c.6471G>T p.Q2157H (on ENST00000614293; = p.Q2127H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/586 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ABCA2 | c.6239T>C p.M2080T (on ENST00000614293; = p.M2050T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ABCA3 | c.2536A>G p.S846G | Missense Mutation (SNP) | VAF 78/428 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ABCA7 | c.2699A>G p.E900G | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC4 | c.2648del p.L883Wfs*7 | Frame Shift Del (DEL) | VAF 37/297 reads (12%) | called by mutect2, pindel, varscan2
- ABCG1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, varscan2
- AC006538.2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 93/584 reads (16%) | SIFT tolerated, low confidence (0.41); called by muse, mutect2, varscan2
- AC011005.1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 75/512 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ACACA | c.2050A>G p.S684G | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ACSM6 | c.994A>G p.S332G | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ACTA1 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 64/496 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ACVR1B | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS1 | c.1789T>C p.Y597H | Missense Mutation (SNP) | VAF 73/423 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADAMTS14 | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ADAMTS18 | c.3461G>A p.G1154D | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADARB2 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 26/718 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADCK5 | c.583del p.H195Tfs*33 | Frame Shift Del (DEL) | VAF 50/460 reads (11%) | called by mutect2, pindel, varscan2
- ADCY1 | c.1425del p.F475Lfs*14 | Frame Shift Del (DEL) | VAF 33/354 reads (9%) | called by mutect2, pindel
- ADCY2 | c.3091A>G p.M1031V | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGB | c.1457del p.K486Rfs*5 | Frame Shift Del (DEL) | VAF 44/294 reads (15%) | called by mutect2, pindel, varscan2
- ADGRG1 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ADGRG1 | c.1954T>G p.F652V | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ADGRL2 | c.1791del p.K597Nfs*21 | Frame Shift Del (DEL) | VAF 32/241 reads (13%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.16395del p.F5465Lfs*13 | Frame Shift Del (DEL) | VAF 17/173 reads (10%) | called by mutect2, pindel, varscan2
- ADIRF | c.213del p.K71Nfs*5 | Frame Shift Del (DEL) | VAF 33/298 reads (11%) | called by mutect2, pindel, varscan2
- ADM | c.404T>A p.V135D | Missense Mutation (SNP) | VAF 92/582 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ADRA2B | c.443T>G p.L148R | Missense Mutation (SNP) | VAF 100/628 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AFF2 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AGBL2 | c.2252del p.K751Rfs*19 | Frame Shift Del (DEL) | VAF 36/218 reads (17%) | called by mutect2, varscan2
- AHNAK | c.2816T>C p.M939T | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AKR7A2 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 65/456 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AL022312.1 | c.10T>C p.W4R | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALCAM | c.458del p.K153Sfs*34 | Frame Shift Del (DEL) | VAF 23/209 reads (11%) | called by mutect2, pindel, varscan2
- ALCAM | c.694del p.T232Qfs*18 | Frame Shift Del (DEL) | VAF 34/307 reads (11%) | called by mutect2, pindel, varscan2
- ALPK3 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 78/511 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK3 | c.12058_12059del p.K4020Dfs*8 | Frame Shift Del (DEL) | VAF 71/575 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.1007T>A p.L336H | Missense Mutation (SNP) | VAF 67/386 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ANKRD31 | c.4164del p.K1388Nfs*6 | Frame Shift Del (DEL) | VAF 24/181 reads (13%) | called by mutect2, pindel, varscan2
- ANLN | c.2300-1G>A p.X767_splice | Splice Site (SNP) | VAF 26/205 reads (13%) | called by muse, mutect2, varscan2
- ANO8 | c.3493del p.R1165Afs*154 | Frame Shift Del (DEL) | VAF 41/245 reads (17%) | called by mutect2, pindel, varscan2
- ANXA6 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.642); called by muse, mutect2
- AP4B1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- APBA1 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 88/677 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APLF | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 23/310 reads (7%) | called by muse, mutect2
- APOL2 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARHGAP22 | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 77/756 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ARHGEF28 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ARID1A | c.4217_4221del p.P1406Rfs*37 | Frame Shift Del (DEL) | VAF 66/479 reads (14%) | called by mutect2, pindel, varscan2
- ARID4B | c.3044G>A p.G1015D | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 57/452 reads (13%) | called by mutect2, pindel, varscan2
- ARSD | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ARX | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 86/584 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, varscan2
- ASMTL | c.1826del p.G609Vfs*22 | Frame Shift Del (DEL) | VAF 73/499 reads (15%) | called by mutect2, varscan2
- ASPRV1 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 89/446 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ASTN2 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 104/664 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- ASTN2 | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 57/436 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATM | c.5284G>A p.A1762T | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATM | c.7234A>G p.N2412D | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ATP2A1 | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP6V0A2 | c.575T>C p.L192S | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ATP6V0A2 | c.1045A>T p.S349C | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by mutect2, varscan2
- ATXN1 | c.1953del p.F651Lfs*40 | Frame Shift Del (DEL) | VAF 45/316 reads (14%) | called by mutect2, pindel, varscan2
- ATXN10 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- AURKB | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GALT4 | c.409del p.D137Ifs*16 | Frame Shift Del (DEL) | VAF 132/868 reads (15%) | called by mutect2, pindel, varscan2
- B3GNT8 | c.507_508del p.E169Dfs*21 | Frame Shift Del (DEL) | VAF 68/549 reads (12%) | called by pindel, varscan2
- B4GALNT4 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- B4GALT5 | c.1151A>G p.Q384R | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); called by muse, mutect2
- BABAM1 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BEND2 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- BICRA | c.1887del p.A630Rfs*94 | Frame Shift Del (DEL) | VAF 70/479 reads (15%) | called by mutect2, pindel, varscan2
- BICRAL | c.2689del p.T897Qfs*8 | Frame Shift Del (DEL) | VAF 49/437 reads (11%) | called by mutect2, pindel, varscan2
- BLM | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- BRD7 | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- BRSK1 | c.1269G>T p.M423I | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- BRWD3 | c.1149T>A p.S383R | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.536_539dup p.T181Vfs*101 | Frame Shift Ins (INS) | VAF 58/482 reads (12%) | called by pindel, varscan2
- BSN | c.540_541insTCA p.S180dup | In Frame Ins (INS) | VAF 82/554 reads (15%) | called by mutect2, varscan2*
- C16orf70 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- C16orf96 | c.1393A>G p.S465G | Missense Mutation (SNP) | VAF 63/473 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- C17orf49 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- C19orf81 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 64/392 reads (16%) | called by muse, mutect2, varscan2
- C1GALT1C1L | c.30del p.F10Lfs*13 | Frame Shift Del (DEL) | VAF 41/278 reads (15%) | called by mutect2, pindel, varscan2
- C1orf109 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 24/684 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2
- C1orf216 | c.140A>G p.H47R | Missense Mutation (SNP) | VAF 66/443 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C4orf50 | c.641A>T p.E214V (on ENST00000324058; = p.E1446V on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- C4orf54 | c.1742A>C p.K581T | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C8orf34 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 94/583 reads (16%) | SIFT tolerated, low confidence (0.27); called by muse, mutect2, varscan2
- C9orf131 | c.2064del p.S689Afs*47 | Frame Shift Del (DEL) | VAF 48/495 reads (10%) | called by mutect2, pindel, varscan2
- CACNA1B | c.4967C>T p.A1656V | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1E | c.4332G>A p.R1444= | Splice Region (SNP) | VAF 35/325 reads (11%) | called by muse, mutect2, varscan2
- CACNG1 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 42/345 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALY | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 48/580 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CAMSAP2 | c.3635G>T p.R1212M (on ENST00000236925 / NM_001297707.2; = p.R1201M on NM_203459.3) | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- CAPN11 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARM1 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- CARMIL3 | c.3625dup p.Q1209Pfs*21 | Frame Shift Ins (INS) | VAF 55/402 reads (14%) | called by mutect2, pindel, varscan2
- CATSPER1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCDC15 | c.2565G>C p.Q855H | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC150 | c.175dup p.R59Kfs*20 | Frame Shift Ins (INS) | VAF 29/201 reads (14%) | called by mutect2, pindel, varscan2
- CCDC177 | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 108/645 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC38 | c.447del p.A150Qfs*24 | Frame Shift Del (DEL) | VAF 56/420 reads (13%) | called by pindel, varscan2
- CCDC73 | c.1396dup p.S466Kfs*5 | Frame Shift Ins (INS) | VAF 19/182 reads (10%) | called by mutect2, pindel
- CCDC88A | c.784A>G p.R262G | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CCKAR | c.940A>G p.M314V | Missense Mutation (SNP) | VAF 66/528 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCKAR | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.108); called by muse, varscan2
- CCNA1 | c.87del p.L30Sfs*55 | Frame Shift Del (DEL) | VAF 50/397 reads (13%) | called by mutect2, pindel, varscan2
- CCNA1 | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CDC20B | c.1458del p.F486Lfs*12 (on ENST00000381375 / NM_001170402.1; = p.F444Lfs*12 on NM_001145734.2) | Frame Shift Del (DEL) | VAF 30/233 reads (13%) | called by mutect2, pindel, varscan2
1,137 further variants in this file (639 protein-altering or splice-affecting, 416 silent, 82 other) are not listed here.
